TCGA case TCGA-YL-A9WI — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: PROCURE Biobank. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d70eacc-d0c3-4121-bd1a-a47d68ecede5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,184 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 15; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 93 (initial diagnosis): Days to imaging: 93 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 99 (initial diagnosis): Days to imaging: 99 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Days to follow up: 1,623 days (4.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,259.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.03 ng/mL (day 1,259).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YL-A9WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 680 mg.
  Slide TCGA-YL-A9WI-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-YL-A9WI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YL-A9WI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Stable Disease; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.03.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Tumor status: Tumor free; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,623 days; disease-specific survival: no event (censored), 1,623 days; progression-free interval: no event (censored), 1,623 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YL-A9WI-01A-11D-A376-01): tumor purity 0.88, ploidy 2.27, whole-genome doublings 0.
